Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A5SI, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A5SI-01A (Primary Tumor).

[page 1 of 3]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try printing again.

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Ordering Provider

Relevant
Information
Location

Copied To

Report Patient
Demographics
(for verification
purposes)

Date of Birth

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver, hepatic NOS
C22.0

JW 4/2/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

A. Segment V and VI, and gallbladder

Clinical Information

Hepatocellular carcinoma.
Infectious patient: Yes - Hep C positive
Immunocompromised: No
History of neoplasm: No

Diagnosis

A. Liver Segment V and VI, and Gallbladder, Partial Hepatectomy and Cholecystectomy:

- Hepatocellular carcinoma, moderately differentiated
- One large tumor, 3.4 cm in greatest dimension, with microscopic foci of well circumscribed tumor nodules away from the main tumor, possibly represent intrahepatic metastasis
- No lymphovascular invasion identified
- Background cirrhosis and chronic hepatitis
- Resection margins negative for malignancy
- Unremarkable gallbladder
- One benign lymph node
- See synoptic report

Reported by:

[page 2 of 3]
Verified:

Synoptic Report

A: Liver, Resection, Microscopic

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm

REGIONAL LYMPH NODES (pN):

pN0: No regional lymph node metastasis

Number examined: 1

Number involved: 0

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Cirrhosis/fibrosis

*Hepatitis (specify type): Chronic Hepatitis

Gross Description

Received is a single specimen. The requisition and specimen container are labelled with the patient's name [REDACTED]. The cassette and AP identifiers are labelled with the Surgical Number

A. The liver segment measures 7.5 x 6.0 x 5.0 cm. The liver resection margin is inked blue. The surface is nodular and has a cirrhotic appearance. The attached gallbladder measures 9.5 x 3.0 x 2.5 cm and has a smooth surface. There is one lymph node present near the cystic duct resection site measuring 1.3 cm in greatest dimension. Serial sectioning of the liver reveals a tan/yellow solid mass measuring 3.4 x 3.0 x up to 2.8 cm and has a slightly hemorrhagic area measuring 0.8 cm in greatest dimension on one side; it bulges toward one area on the liver surface. The tumor has a lobular appearance and is at least 1.5 cm from the liver resection margin. The rest of the liver parenchyma appears nodular, with areas of green discoloration. No second mass lesion is identified. Grossly, the liver mass does not adhere or invade into the gallbladder. Opening of the gallbladder reveals dark green velvety inner lining, with no calculi present and no grossly identifiable lesion on the inner lining.

Sections are submitted as follows:

A1 - liver mass with the bulging surface.

A2 - tumor with liver resection margin.

A3 through A5 - mass with hemorrhagic area in A4.

A6 - additional tumor with resection margin.

A7 - gallbladder with underlying liver.

A8 - liver tissue away from the mass.

A9 - cystic duct margin.

A10 - lymph node near the cystic duct, bisected.

A11 - section of a small 0.2 cm nodular that is 0.8 cm away from the main mass.

[page 3 of 3]
Pathologist Comment
Dr. has reviewed selected slides.

Accession
Number
Encounter
Number
Patient Location

– END OF PRINTED REPORT –

HPV A Discrepancy		☒
Primary Discrepancy History		☒
Discrepancy Primary Report		☒

Source: NCI Genomic Data Commons file 067954f0-c96f-4ca9-9fe2-96798acd77c4 (TCGA-G3-A5SI.C3CB3D42-9123-4D51-9FA8-D272D5F62F7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).